TCGA case TCGA-06-0195 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/67e2af1c-3478-4652-8759-b9d5c5b6a3e0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 225 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 63.3 years (23,132 days); Year of diagnosis: 1994; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 47 days; Days to treatment end: 79 days; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine + Procarbazine + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 95 days; Days to treatment end: 169 days; Number of cycles: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 169 days; Days to treatment end: 200 days; Number of cycles: 1.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 63.7 years (23,279 days); Days to diagnosis: 147 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 147 (post initial treatment): Progression or recurrence: Yes; Days to progression: 147 days.
- Days to follow up: 214 days; Disease response: With Tumor.
- Days to follow up: 225 days; Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0195-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-0195-01B-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-06-0195-01B-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-06-0195-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0195-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 2: Pharmaceutical therapy drug name: VP 16 (Etoposide).
- Radiation treatment: Therapy regimen other: Per site no other information available in medical records.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 225 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 225 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 147 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0195-01B-01D-0236-01): tumor purity 0.69, ploidy 3.23, whole-genome doublings 1.
